Surgical pathology report (de-identified scan), TCGA case TCGA-29-1768, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Duke, specimen TCGA-29-1768-01A (Primary Tumor).

[page 1 of 2]
TCGA-29-1768

Surg Path

CLINICAL HISTORY:

Ovarian cyst.

GROSS EXAMINATION:

A. "Omentum", received fresh. A 19 x 13 x 2.5 cm firm, nodular, matted fragment of yellow-tan omental tissue is received. Sectioning reveals yellow fat intermixed with dense bands of white, fibrous tumor tissue. Areas of fat necrosis are focally appreciated. Representative sections are submitted in Blocks A1-3.

B. "Right ovary and tube", received fresh. A 3 gram aggregate of tissue composed of a 3.9 x 0.8 cm slightly edematous fimbriated fallopian tube adherent upon a focally disrupted 4.5 x 3.7 x 2 cm ovary with a nodular, friable cut surface. Representative sections are submitted in Blocks B1-3.

C. "Left tube and ovary", received fresh. A 26 gram aggregate of tissue composed of fimbriated ends of a fallopian tube adherent upon a nodular, focally disrupted 5 x 3.8 x 3.2 cm ovary. Sectioning through the ovary reveals a focally solid cut surface and a peripheral clear, fluid-filled thin-walled 2.2 cm diameter cyst. The cyst itself is lined by smooth, glistening surfaces surrounded by normal-appearing ovarian tissue. The nodularity appears to be on the edge of the ovary in the fibrofatty tissue (C2-3). Representative sections are submitted in Blocks C1-3.

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

PATHOLOGIC STAGE:

PROCEDURE: Bilateral salpingo-oophorectomy and omental biopsy

PATHOLOGIC STAGE (AJCC 6th Edition): pT3c pNx pMX

NOTE: Information on pathology stage and the operative procedure is transmitted to this [REDACTED] as required for accreditation by the [REDACTED]. Pathology stage is based solely upon the current tissue specimen being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section, past pathology information, imaging studies, or clinical or operative findings. Pathology stage is only a component to be considered in determining the clinical stage, and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

DIAGNOSIS:

A.. "OMENTUM" (BIOPSY):

METASTATIC SEROUS ADENOCARCINOMA, POORLY DIFFERENTIATED.

/ B. "RIGHT OVARY AND TUBE" (SALPINGO-OOPHORECTOMY):

TYPE: PAPILLARY SEROUS ADENOCARCINOMA
FIGO GRADE: III (POORLY DIFFERENTIATED)
TUMOR SIZE: 4.5 X 3.7 X 2.0 CM.
WEIGHT: 3 GRAMS
SEROSA: INVOLVED

[page 2 of 2]
TCGA-29-1768

ADDITIONAL FINDINGS: _

SPECIMENS WITH METASTATIC/IMPLANTED TUMOR
OMENTUM.

B. "LEFT TUBE AND OVARY" (SALPINGO-OOPHORECTOMY):

TYPE: PAPILLARY SEROUS ADENOCARCINOMA
FIGO GRADE: III (POORLY DIFFERENTIATED)
TUMOR SIZE: 5.0 X 3.8 X 3.2 CM.
WEIGHT: 26 GRAMS
Serosa: INVOLVED.
ADDITIONAL FINDINGS: _

SPECIMENS WITH METASTATIC/IMPLANTED TUMOR
OMENTUM

SEE COMMENT.

[REDACTED]

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

[REDACTED]

Performed by: [REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 41363970-8e19-4e23-a670-88dc1d0b3d20 (TCGA-29-1768.12D9B343-A52D-4A36-BA7B-31BFEB66DA50.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).